CCDI case PBCEVI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/46c65f9c-26d9-4d43-83cd-c2a98b60dc21

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,456 days).

Biospecimens (3 samples)
- Sample 0DQB25: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQB2N: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQB2W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
